CGCI case HTMCP-02-03-01017 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3ad32bb2-665b-4c2b-b9ae-5ddba44371e5

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Dead; Days to death: 1,686 days (4.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 59.8 years (21,829 days); Year of diagnosis: 2011; Method of diagnosis: Fine Needle Aspiration; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,683 days (4.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 1,683 days (4.6 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -4,234.

Other clinical attributes
- Day -4,234: Risk factors: HIV/AIDS.
- Day -4,234: Comorbidities: HIV/AIDS.
- Day 0: Cdc hiv risk factors: Heterosexual Contact.
- Day 0: Risk factors: Hepatitis B Infection.
- Day 0: Weight: 93.5 kg; Height: 162.6 cm; BMI: 35.4; CD4 count: 700; HIV viral load: 0.
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 0: AIDS risk factors: Pneumocystis Pneumonia.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 22; Tobacco smoking quit year: 2011.

Biospecimens (3 samples)
- Sample HTMCP-02-03-01017-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01017-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-03-01017-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); Tumor status: Tumor free; Tobacco smoking age started: 15; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Treatment outcome first course: Complete Remission/Response; Tobacco smoking history indicator: 4; New tumor event diagnosis indicator: No.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Lower lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1999; HIV rna load at diagnosis: 0; Prior aids conditions: Pneumocystis jirovecii pneumonia; History relevant infectious diagnosis: Hepatitis B Virus.
- Primary pathology: Method initial path diagnosis: Fine needle aspiration biopsy; Days from index date to tumor sample procurement: 49.
